Somatic mutation profile of tumor specimen ASCProject_0166_T1_WES (aliquot ASCProject_0166_T1_WES_1) from CMI case ASCProject_0166, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 58.6 years (21,398 days).
Specimen ASCProject_0166_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Submandibular; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3de2d939-70df-4344-bfb5-6eb0d6932655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0166_SALIVA_2 (Saliva), aliquot ASCProject_0166_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1527bb5e-1cea-4260-9d17-7d224a9ebd18

The open-access MAF lists 2,000 somatic variants for this specimen: 1,141 protein-altering or splice-affecting, 592 silent, 267 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,028, Silent 592, Intron 128, Nonsense Mutation 71, RNA 42, 5'Flank 32, 5'UTR 29, 3'UTR 28, Splice Region 22, Splice Site 16, 3'Flank 8, Translation Start Site 2.

Variants (750 of 2,000; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.1987-1G>A p.X663_splice | Splice Site (SNP) | VAF 28/376 reads (7%) | catalogued as rs1060499714; ClinVar: pathogenic; called by muse, mutect2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBX18 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs886041719; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2
- ABCA9 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100383106, COSV60626474; called by muse, mutect2
- ABCB1 | c.944G>A p.W315* | Nonsense Mutation (SNP) | VAF 22/286 reads (8%) | catalogued as rs1189919755; called by muse, mutect2
- ABCB11 | c.3875G>A p.G1292E | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM097373; called by muse, mutect2
- ABCB11 | c.3874G>A p.G1292R | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55597225; called by muse, mutect2
- ABCC12 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100252884; called by muse, mutect2
- ABCC4 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); catalogued as COSV65313348; called by muse, mutect2
- ABCG2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1272411168, COSV52948003; called by muse, mutect2
- ABTB2 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs866789448; called by muse, mutect2
- ACACB | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV58137060; called by muse, mutect2
- ACAN | c.5039G>A p.G1680E | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1320141954, COSV61366627; called by muse, mutect2
- ACSM2A | c.539A>G p.K180R (on ENST00000219054; = p.K101R on NM_001308169.2) | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs1268020126; called by muse, mutect2
- ACSS3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1423395537; called by muse, mutect2, varscan2
- ADAMTS4 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63489436; called by muse, mutect2
- ADCY10 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.236); catalogued as COSV63244828; called by muse, mutect2, varscan2
- ADCY4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1469392912; called by muse, mutect2
- AGBL1 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750108622, COSV66849667; called by mutect2, varscan2
- AGFG2 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53546943; called by muse, mutect2, varscan2
- AGRN | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 130/619 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV65071471; called by muse, mutect2, varscan2
- AGTR1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as COSV62557161; called by muse, mutect2
- AGXT | c.846+7G>A | Splice Region (SNP) | VAF 44/376 reads (12%) | catalogued as rs1209077784; called by muse, varscan2
- ALK | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202835; called by muse, mutect2
- ANGPT1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV52440135; called by muse, mutect2
- ANHX | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161912214; called by muse, mutect2
- ANKRD11 | c.5920C>T p.P1974S | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1395778977, COSV56366728; called by muse, mutect2
- ANKRD24 | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs1486998725; called by muse, mutect2
- ANKRD35 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs141824672; called by muse, mutect2, varscan2
- ANKS1B | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV61380433; called by muse, mutect2
- ANKS1B | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1253061282; called by muse, mutect2
- APBA3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV100349691; called by muse, mutect2
- APC | c.3970C>T p.P1324S | Missense Mutation (SNP) | VAF 38/507 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs587779792; ClinVar: uncertain significance; called by muse, mutect2
- APOB | c.7762C>T p.P2588S | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178162332, COSV51932764; called by muse, mutect2
- AREG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 54/696 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765591544, COSV52644609; called by muse, mutect2
- ARHGAP6 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.381); catalogued as rs748783518; called by muse, mutect2, varscan2
- ARHGDIG | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as COSV54731673; called by muse, mutect2, varscan2
- ARHGEF26 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1368052860, COSV100726568; called by muse, mutect2
- ASL | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM141222; called by muse, mutect2
- ASTN2 | c.3389C>T p.S1130F (on ENST00000313400 / NM_001365069.1; = p.S1079F on NM_014010.5) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV56012674, COSV99939975; called by muse, mutect2
- ASXL3 | c.4429C>T p.H1477Y | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52457989; called by muse, mutect2
- ATP8B4 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867660365; called by muse, mutect2
- ATXN7L2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs910593265; called by muse, mutect2
- AXIN2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV61058222; called by muse, mutect2
- B4GALNT2 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs948639038, COSV55924416; called by muse, mutect2, varscan2
- BEND4 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as rs1484412776; called by muse, mutect2
- BICC1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1436299776; called by muse, mutect2
- BLK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1013048438, COSV52056498; called by muse, mutect2
- BNC2 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.992); catalogued as rs1258317874; called by muse, mutect2
- BTG4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749155001; called by mutect2, varscan2
- C10orf67 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV64728331, COSV64729651; called by muse, mutect2
- C14orf39 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1305335490, COSV58780862; called by muse, mutect2
- C1orf141 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs868866615; called by muse, mutect2
- C2orf66 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1466076088; called by muse, mutect2
- C4BPA | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65537105; called by muse, varscan2
- C6 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs1401668528; called by muse, mutect2
- C8A | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as COSV63483073; called by muse, mutect2, varscan2
- C9orf92 | n.84G>A | Splice Region (SNP) | VAF 16/121 reads (13%) | catalogued as rs1302471075; called by muse, mutect2, varscan2
- CACNA1F | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100544681; called by muse, mutect2, varscan2
- CACNA1H | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1368473639; called by muse, mutect2
- CACNA2D1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62374760, COSV62376147; called by muse, mutect2
- CAPN8 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1333594036; called by muse, varscan2
- CASP8AP2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs991284602; called by muse, mutect2
- CAT | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99573218, COSV99573294; called by muse, mutect2
- CCDC116 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1280419862, COSV53042029; called by muse, mutect2
- CCDC163 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV59151305; called by muse, mutect2, varscan2
- CCSER1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255659915; called by muse, mutect2
- CDC42BPG | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs995862179; called by muse, mutect2, varscan2
- CDH8 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54855696; called by muse, mutect2
- CDT1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1222100253; called by muse, mutect2
- CECR2 | c.3262G>A p.G1088R (on ENST00000342247 / NM_001290047.2; = p.G904R on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as rs867656211; called by muse, mutect2
- CELSR1 | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs141040650; called by mutect2, varscan2
- CFAP54 | c.6103C>T p.P2035S | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1277930990; called by muse, mutect2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by mutect2, varscan2
- CHAF1A | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56673514; called by muse, mutect2
- CHD5 | c.4895C>T p.P1632L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs201640978, COSV52409150; called by muse, mutect2, varscan2
- CHST15 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60566571; called by muse, mutect2
- CLASP1 | c.4255C>T p.H1419Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as rs1428724535; called by muse, mutect2
- CLDN25 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs753511689; called by muse, mutect2, varscan2
- CNPPD1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.201); catalogued as rs1472603017; called by muse, mutect2
- COL14A1 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1316632101; called by muse, mutect2
- COL1A2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 42/630 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.197); catalogued as COSV99800455; called by muse, mutect2
- COL2A1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1359971369, COSV61531121; called by muse, mutect2
- COL4A4 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61629553; called by muse, mutect2
- COL6A3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as rs1553564820; ClinVar: uncertain significance; called by muse, mutect2
- CP | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52830548; called by muse, mutect2
- CPEB2 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.759); catalogued as rs1209285691; called by muse, mutect2
- CPS1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 31/421 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242311; called by muse, mutect2
- CPT1A | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV55752831; called by muse, mutect2
- CR1 | c.5237A>T p.K1746I | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1196832040; called by muse, mutect2
- CR2 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 31/521 reads (6%) | catalogued as rs1227539111; called by muse, mutect2
- CRPPA | c.845C>T p.S282F (on ENST00000407010 / NM_001368197.1; = p.S232F on NM_001101417.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1187330759, COSV67907310; called by muse, mutect2
- CSF2RA | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as rs201854740, COSV100818008, COSV62623853; called by muse, mutect2
- CSMD1 | c.3940G>A p.G1314R (on ENST00000520002; = p.G1313R on NM_033225.6) | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100152931; called by muse, mutect2
- CSMD2 | c.7285G>A p.G2429R | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99592856; called by muse, mutect2, varscan2
- CSMD2 | c.4330C>T p.P1444S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs368646887, COSV53962675; called by mutect2, varscan2
- CSMD3 | c.7471G>A p.E2491K (on ENST00000297405 / NM_001363185.1; = p.E2387K on NM_052900.3) | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52164484; called by muse, mutect2
- CSMD3 | c.6829C>T p.P2277S (on ENST00000297405 / NM_001363185.1; = p.P2173S on NM_052900.3) | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52183283; called by muse, mutect2
- CSMD3 | c.5873C>T p.P1958L (on ENST00000297405 / NM_001363185.1; = p.P1854L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1452247908, COSV52188668; called by muse, mutect2
- CSMD3 | c.4798C>T p.L1600F (on ENST00000297405 / NM_001363185.1; = p.L1496F on NM_052900.3) | Missense Mutation (SNP) | VAF 43/531 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52158139, COSV99835789; called by muse, mutect2
- CTAG2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs200456175; called by muse, mutect2, varscan2
- CYLC2 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); catalogued as COSV66336089; called by muse, mutect2
- CYP2C8 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 37/450 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs868818549; called by muse, mutect2
- CYP3A43 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV99733194; called by muse, mutect2
- CYP4F11 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56130036; called by muse, mutect2
- CYP4F2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167523556; called by muse, mutect2
- CYP4X1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64149533; called by muse, mutect2, varscan2
- DACH2 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100913734, COSV64177967; called by muse, mutect2, varscan2
- DAPK3 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100009609, COSV56665218; called by muse, mutect2
- DAZL | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51714482; called by muse, mutect2
- DCC | c.4308G>A p.M1436I | Missense Mutation (SNP) | VAF 70/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV71440013; called by muse, mutect2, varscan2
- DDX1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV51839355; called by muse, mutect2
- DDX43 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64812467; called by muse, mutect2
- DEPDC7 | c.526G>A p.E176K (on ENST00000241051 / NM_001077242.2; = p.E167K on NM_139160.2) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.054); catalogued as rs1489779983; called by muse, mutect2
- DLG2 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV54625070, COSV99719151; called by muse, mutect2
- DLG2 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as COSV54641221; called by muse, mutect2
- DLGAP2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101421639; called by muse, mutect2, varscan2
- DMBT1 | c.3148C>T p.Q1050* (on ENST00000338354 / NM_001377530.1; = p.Q551* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 38/616 reads (6%) | catalogued as COSV57559042; called by muse, mutect2
- DMD | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as CM022955; called by muse, mutect2, varscan2
- DMD | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.257); catalogued as COSV55877803; called by muse, mutect2
- DNAAF1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57576923; called by muse, mutect2
- DNAH1 | c.5125C>T p.P1709S | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70228537, COSV70231516; called by muse, mutect2
- DNAH10 | c.1543G>A p.E515K (on ENST00000409039; = p.E454K on NM_207437.3) | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1445065172, COSV69003141; called by muse, mutect2
- DNAH11 | c.5335C>T p.Q1779* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV100179377, COSV60972086; called by muse, mutect2
- DNAH2 | c.6763C>T p.R2255C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs779616636, COSV66717851; called by mutect2, varscan2
- DNAH5 | c.12625C>T p.P4209S | Missense Mutation (SNP) | VAF 35/487 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868612793, COSV54201291; called by muse, mutect2
- DNAH7 | c.11321C>T p.P3774L | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348468083; called by muse, mutect2
- DNAH8 | c.5579G>A p.G1860E | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs989332520, COSV59477165; called by muse, mutect2
- DNAI1 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54285683; called by muse, mutect2
- DNAJC1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256726390; called by muse, mutect2
- DOP1B | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54281968; called by muse, mutect2
- DPP10 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071592; called by muse, mutect2
- DPP8 | c.1066-1G>A p.X356_splice (on ENST00000341861 / NM_001320875.2; = p.X340_splice on NM_017743.6) | Splice Site (SNP) | VAF 7/69 reads (10%) | catalogued as COSV55678426; called by muse, mutect2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2
- DSC1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as COSV57144137; called by muse, mutect2
- DSCAM | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV68024455; called by muse, mutect2
- DSCAM | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68031995; called by muse, mutect2
- DSG1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV57138246; called by muse, mutect2, varscan2
- DSG4 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1354094291; called by muse, mutect2, varscan2
- DSP | c.3674C>T p.S1225F | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV101131528; called by muse, mutect2
- DUOX2 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1156851013; called by muse, mutect2
- ECM1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV100682252; called by muse, mutect2
- EFCAB3 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59500132; called by muse, mutect2
- EFCAB5 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954918050, COSV100300630; called by muse, mutect2, varscan2
- EGFLAM | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100472173; called by muse, mutect2
- EIF2B2 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 51/626 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV56721624; called by muse, mutect2
- ELOVL4 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 21/493 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV100876420; called by muse, mutect2
- ENPEP | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV54446892; called by muse, mutect2
- ENTPD8 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV58163746; called by muse, mutect2, varscan2
- EPB41L3 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.14); catalogued as rs1382455128; called by muse, mutect2
- EPB41L3 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374164318, COSV59464538; called by muse, varscan2
- EPHA8 | c.2774G>A p.G925E | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs201047906; called by muse, mutect2, varscan2
- EPHB1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV67659836; called by muse, mutect2
- EPHB2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs769893752; called by mutect2, varscan2
- EPHB6 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1375945064; called by muse, mutect2
- EPPK1 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868984315; called by muse, mutect2
- EPPK1 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs570137863, COSV73262358; called by muse, mutect2
- EYA4 | c.1778G>A p.R593Q (on ENST00000531901 / NM_001301013.1; = p.R587Q on NM_004100.5) | Missense Mutation (SNP) | VAF 47/577 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746014018, COSV62052527; called by muse, mutect2
- EYS | c.7957G>A p.D2653N | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV65498298; called by muse, mutect2
- F11 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); catalogued as rs1219290117, COSV99251472; called by muse, mutect2
- FABP12 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV64616811, COSV64616879; called by muse, mutect2
- FAM117B | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs1284906020; called by muse, mutect2
- FAM189A1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54287628; called by muse, mutect2
- FAM20A | c.1302G>A p.G434= | Splice Region (SNP) | VAF 28/413 reads (7%) | catalogued as rs952058870; called by muse, mutect2
- FAM234A | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV56995719; called by muse, mutect2
- FAM47A | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs1362874307; called by muse, mutect2, varscan2
- FANK1 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1564937866, COSV64156130, COSV64156194; called by muse, mutect2, varscan2
- FAT2 | c.7963C>T p.Q2655* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV55820677, COSV55822593; called by muse, mutect2
- FAT2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1259896022, COSV55832327; called by muse, mutect2
- FAT3 | c.7288G>A p.E2430K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs865851102, COSV53130236; called by muse, mutect2, varscan2
- FBLN1 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1245694774; called by muse, mutect2
- FBLN1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 38/511 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs1380071981; called by muse, mutect2
- FBLN1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV53049662; called by muse, mutect2
- FBN2 | c.5411G>A p.G1804E | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52509981; called by muse, mutect2
- FBXO36 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202219810; called by muse, mutect2
- FCER1A | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV63666680; called by muse, mutect2
- FFAR1 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 38/623 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1208882685; called by muse, mutect2
- FGFR2 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.286); catalogued as COSV100337466; called by muse, mutect2
- FLG | c.9473C>T p.S3158F | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV64250027; called by muse, varscan2
- FLG2 | c.4534G>A p.G1512R | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.427); catalogued as COSV66167101; called by muse, mutect2, varscan2
- FLNB | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99915509; called by muse, mutect2
- FMNL2 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 22/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186403207; called by muse, mutect2
- FN1 | c.4258C>T p.P1420S | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100116532; called by muse, mutect2
- FRY | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV66580431; called by muse, mutect2
- FSHR | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287744138; called by muse, mutect2
- FSTL5 | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1348028326; called by muse, mutect2
- GABRA5 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59485184; called by muse, mutect2
- GABRR3 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV101512264; called by muse, mutect2
- GALNT14 | c.1505G>A p.W502* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV61108641; called by muse, mutect2
- GFRAL | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV61229621; called by muse, mutect2, varscan2
- GJA5 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs281860596; called by muse, mutect2, varscan2
- GJA8 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV99569291; called by muse, mutect2, varscan2
- GJC1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57912777; called by muse, mutect2
- GLYATL3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64592717; called by muse, mutect2
- GP6 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777656189, COSV59977392; called by muse, mutect2
- GPATCH8 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs1256078743; called by muse, mutect2
- GPR19 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1417730307; called by muse, mutect2
- GRIA3 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52067487; called by muse, mutect2
- GRIN3A | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs867585563, COSV62457494; called by muse, mutect2
- GRK2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1208435182; called by muse, mutect2
- GRM7 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV63127504; called by muse, mutect2
- HAO1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV66492278, COSV66493195; called by muse, mutect2, varscan2
- HAO2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV58038856; called by muse, mutect2
- HCN3 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs144344896, COSV61361955; called by muse, mutect2, varscan2
- HEPHL1 | c.2644A>G p.I882V | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.401); catalogued as COSV59897945; called by muse, mutect2
- HJV | c.379C>T p.P127S (on ENST00000336751 / NM_213653.4; = p.P14S on NM_145277.5) | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781820733; called by muse, mutect2
- HLF | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1362948140, COSV56830361; called by muse, mutect2
- HMCN1 | c.8108C>T p.S2703F | Missense Mutation (SNP) | VAF 59/414 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV99626162; called by muse, mutect2, varscan2
- HNRNPCL2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1267221984, COSV60404769; called by muse, mutect2
- HNRNPM | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs951189809, COSV57692340; called by muse, mutect2
- HOXD4 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV60459970; called by muse, mutect2
- HSD3B1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV52492717; called by muse, mutect2
- HTR6 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1235805550, COSV53869990; called by muse, mutect2, varscan2
- ICAM5 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as rs1209662184; called by muse, mutect2
- IGHG2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 36/904 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1567187367; called by muse, mutect2
- IGHV1-18 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs578104719; called by muse, mutect2, varscan2
- IGLV5-45 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 41/257 reads (16%) | catalogued as rs183116743; called by muse, varscan2
- IL17RD | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.335); catalogued as rs1560193175, COSV56334852, COSV56342947; called by muse, mutect2
- ING1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100311914; called by muse, mutect2
- INO80D | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68960231; called by muse, mutect2
- INPP5B | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as rs200195945; called by muse, mutect2, varscan2
- INSC | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV101088919; called by muse, mutect2
- IQCA1 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1400136232, COSV54500495; called by muse, mutect2
- IQCC | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as rs535162815, COSV52210666; called by muse, mutect2, varscan2
- IRX1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 26/382 reads (7%) | catalogued as COSV57360798; called by muse, mutect2
- ITK | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV68435461; called by muse, mutect2
- JADE3 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509829; called by muse, mutect2
- JAG2 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 27/419 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as rs1243186714; called by muse, mutect2
- JAM2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV57257601; called by muse, mutect2
- JMJD6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.254); catalogued as rs1163022715; called by muse, mutect2, varscan2
- JPH3 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1319951040; called by muse, mutect2
- KBTBD6 | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV65271512; called by muse, mutect2
- KCNA2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60369441; called by muse, mutect2
- KCNMB2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV64201783; called by muse, mutect2
- KCNN2 | c.371G>A p.R124Q (on ENST00000264773; = p.R336Q on NM_021614.4) | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53298825; called by muse, mutect2
- KCTD8 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63591388; called by muse, mutect2
- KIAA0825 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV56950700; called by muse, mutect2
- KIAA1210 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99081429; called by muse, mutect2, varscan2
- KIF17 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 88/460 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.111); catalogued as COSV99929942; called by muse, mutect2, varscan2
- KIF19 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1377460311, COSV63429906; called by muse, mutect2
- KIF2B | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV52132472; called by muse, mutect2
- KIF5C | c.294G>A p.G98= | Splice Region (SNP) | VAF 16/129 reads (12%) | catalogued as COSV69171228; called by muse, mutect2, varscan2
- KLHL1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | catalogued as COSV64783534; called by muse, mutect2
- KLHL13 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV53244388; called by muse, mutect2
- KLHL26 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1405795708; called by muse, mutect2, varscan2
- KMT2A | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs781985434, COSV100630344; called by muse, mutect2
- KRT16 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1324353859; called by muse, mutect2
- KRT4 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV53406492; called by muse, mutect2
- KRT6A | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 42/1042 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV58107860; called by muse, mutect2
- KRT75 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs868773254, COSV52871158; called by muse, mutect2
- KRT84 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1199593174; called by muse, mutect2
- L1CAM | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100649507; called by muse, mutect2, varscan2
- LAMB4 | c.5156G>A p.R1719K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52713387, COSV52732038; called by muse, mutect2, varscan2
- LAMC3 | c.3164G>A p.G1055E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV63096567; called by mutect2, varscan2
- LDLR | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs868801795; called by muse, mutect2
- LMOD2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867202371, COSV71755577; called by muse, mutect2
- LOXL4 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 66/852 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774923141; called by muse, mutect2
- LRP2 | c.6916G>A p.E2306K | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as COSV55546489; called by muse, mutect2
- LRP2 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867826289; called by muse, mutect2
- LRP2 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV55543493; called by muse, mutect2
- LRRK2 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54157855, COSV54162951; called by muse, mutect2
- LRRK2 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54147834; called by muse, mutect2
- LRTM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs773408157, COSV99836070; called by muse, mutect2
- LSR | c.1837G>A p.E613K (on ENST00000361790; = p.E594K on NM_015925.6) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs770452111; called by mutect2, varscan2
- LTF | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs926574840, COSV51610704; called by muse, mutect2
- LTN1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV63733649; called by muse, mutect2
- MAGEC1 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1191882102, COSV53572589; called by muse, mutect2, varscan2
- MAL2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV52662020; called by muse, mutect2, varscan2
- MAMLD1 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782323826, COSV99475910; called by muse, mutect2, varscan2
- MAN1C1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1453779428, COSV99848722; called by muse, mutect2, varscan2
- MAP2 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV52296878; called by muse, mutect2, varscan2
- MAP4K4 | c.1871C>T p.P624L (on ENST00000347699 / NM_001242559.2; = p.P539L on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1277385716; called by muse, mutect2
- MAP7D1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV60214839; called by muse, mutect2, varscan2
- MARK3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1378018680; called by muse, mutect2, varscan2
- MCAT | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs964305800; called by muse, mutect2
- MEAF6 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV56164458; called by muse, mutect2, varscan2
- MED25 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV57206963; called by muse, mutect2
- METTL11B | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV101464201; called by muse, mutect2, varscan2
- METTL27 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1554636615; called by muse, mutect2
- METTL9 | c.751+1G>A p.X251_splice | Splice Site (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100820538; called by muse, mutect2
- MGAM | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV71885178; called by muse, mutect2
- MIB2 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV61543457; called by muse, mutect2
- MICAL2 | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2
- MINDY4B | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1245863552; called by muse, mutect2
- MIPOL1 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1436133259, COSV59380191; called by muse, mutect2
- MKNK1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57861337; called by muse, mutect2, varscan2
- MLYCD | c.799-4C>T | Splice Region (SNP) | VAF 32/407 reads (8%) | catalogued as rs1434940922; called by muse, mutect2
- MMP20 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 43/727 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs1179879872; called by muse, mutect2
- MN1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761152707; called by mutect2, varscan2
- MPO | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770768376; called by muse, mutect2, varscan2
- MRNIP | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as COSV52976401; called by muse, mutect2
- MROH2B | c.4551G>A p.W1517* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV101270617, COSV68189096; called by muse, mutect2, varscan2
- MROH5 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV71301744; called by muse, mutect2
- MS4A1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV61942241; called by muse, mutect2
- MS4A1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1313395216, COSV100619394; called by muse, mutect2
- MS4A14 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55737042; called by muse, mutect2
- MTOR | c.7234G>A p.D2412N | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63879461; called by muse, mutect2, varscan2
- MUC12 | c.15824C>T p.S5275F (on ENST00000379442; = p.S5132F on NM_001164462.1) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.77); catalogued as rs1295108316; called by muse, mutect2
- MUC16 | c.25589G>A p.G8530E | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as COSV67448821; called by muse, mutect2
- MUC16 | c.25354G>A p.E8452K | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV67468567; called by muse, mutect2
- MUC16 | c.14695G>A p.E4899K | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.047); catalogued as COSV101200985; called by muse, mutect2
- MUC16 | c.12032C>T p.S4011F | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67460203; called by muse, mutect2
- MUC16 | c.6436C>T p.L2146F | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs935083537, COSV101199598, COSV67464082, COSV67478986; called by muse, mutect2
- MXRA5 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54249955; called by mutect2, varscan2
- MYF5 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57354993; called by muse, mutect2
- MYH1 | c.5812G>A p.E1938K | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV56857086; called by muse, mutect2
- MYH11 | c.2815C>T p.Q939* | Nonsense Mutation (SNP) | VAF 26/438 reads (6%) | catalogued as COSV55554464; called by muse, mutect2
- MYH14 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as rs910420638; called by muse, mutect2, varscan2
- MYH2 | c.5304C>T p.A1768= | Splice Region (SNP) | VAF 45/534 reads (8%) | catalogued as rs562803081, COSV55442713; called by muse, mutect2
- MYH2 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1219331596, COSV55440054; called by muse, mutect2
- MYO15A | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.935); catalogued as rs1567621012; called by muse, mutect2
- MYO15A | c.7685C>T p.S2562F | Missense Mutation (SNP) | VAF 52/710 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs876657904; ClinVar: uncertain significance; called by muse, mutect2
- MYO18B | c.7021C>T p.P2341S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV59133838; called by muse, mutect2
- MYO5B | c.5099G>A p.R1700Q | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771703731; called by muse, varscan2
- MYOD1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV51454620; called by muse, mutect2
- MYOM1 | c.3916G>A p.E1306K | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV55285349; called by muse, mutect2, varscan2
- NAT2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as rs753856548, COSV54061995; called by mutect2, varscan2
- NBAS | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.653); catalogued as rs866659468, COSV55722010; called by muse, mutect2
- NBPF10 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782580740, COSV61248552; called by muse, mutect2
- NCF4 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs376569226; called by muse, mutect2
- NDST4 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52115115; called by muse, mutect2
- NEK9 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.506); catalogued as COSV53132025; called by muse, mutect2
- NF1 | c.7846C>T p.Q2616* (on ENST00000358273 / NM_001042492.3; = p.Q2595* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 29/385 reads (8%) | catalogued as CM021311, COSV62221287; called by muse, mutect2
- NFATC4 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.276); catalogued as rs576702065; called by mutect2, varscan2
- NHLRC1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1467326281; called by muse, mutect2
- NLRP13 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV61622011, COSV61623829; called by muse, mutect2, varscan2
- NLRP9 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243099; called by muse, mutect2
- NOVA1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.04); catalogued as COSV99947022; called by muse, mutect2
- NPBWR2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63899758; called by muse, mutect2
- NTRK3 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs1456055401; called by muse, mutect2, varscan2
- NUCKS1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | catalogued as COSV63347869; called by muse, mutect2
- NUP210L | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1304865611, COSV55141324; called by muse, mutect2
- NUTM2A | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs1317258840; called by muse, mutect2
- OBSCN | c.11162G>A p.R3721K | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99483983; called by muse, mutect2
- ODF3L2 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443716151; called by muse, mutect2
- OR10A3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs760300427; called by muse, mutect2
- OR10G8 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1441589267; called by muse, mutect2
- OR10J3 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV100171858; called by muse, mutect2
- OR10J3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs777818775, COSV59953436, COSV59954444; called by muse, mutect2, varscan2
- OR10K1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56874545; called by muse, mutect2, varscan2
- OR10S1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV73343063; called by muse, mutect2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, mutect2, varscan2
- OR2AK2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs767778692, COSV100822935; called by mutect2, varscan2
- OR2G2 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs866761315, COSV60739287; called by muse, mutect2
- OR2G6 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58573668; called by muse, mutect2
- OR2L2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs781308401; called by mutect2, varscan2
- OR2T11 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.684); catalogued as rs867929200, COSV58185921; called by muse, mutect2
- OR4C6 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV58603831, COSV58604646; called by muse, mutect2
- OR51F1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100598644, COSV58580224; called by muse, mutect2
- OR51M1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV60784234, COSV60784280, COSV60785593; called by muse, mutect2
- OR51T1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59025557, COSV59026954; called by muse, mutect2
- OR56A5 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as rs767990347; called by mutect2, varscan2
- OR5M8 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1189381094; called by muse, mutect2
- OR6N2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs144962739; called by muse, mutect2, varscan2
- OR8B8 | c.133T>A p.L45M | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV60144447; called by muse, mutect2
- OTOG | c.6928C>T p.R2310C | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs911133343, COSV100695754; called by muse, mutect2
- OTOL1 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60008498; called by muse, mutect2
- OTOP3 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV60914367; called by muse, mutect2
- OTX2 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV59765477; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.840G>A p.M280I (on ENST00000374531 / NM_001037293.2; = p.M312I on NM_053016.6) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1181980392, COSV57119104; called by muse, mutect2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 38/234 reads (16%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PARD3B | c.2924C>T p.P975L (on ENST00000406610 / NM_001302769.2; = p.P906L on NM_057177.7) | Missense Mutation (SNP) | VAF 37/441 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs377577034, COSV62534123; called by muse, mutect2
- PAX4 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100489920; called by muse, mutect2
- PCDH15 | c.4984G>A p.E1662K (on ENST00000644397 / NM_001354429.2; = p.E1604K on NM_001142771.2) | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.304); catalogued as COSV64670429; called by muse, mutect2
- PCDH15 | c.4938G>A p.M1646I | Missense Mutation (SNP) | VAF 44/673 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs865790836, COSV57358332; called by muse, mutect2
- PCDH15 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV57312185, COSV57372906; called by muse, mutect2
- PCDH18 | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61266424; called by muse, mutect2
- PCDHA11 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs781872546; called by muse, mutect2
- PCDHA2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.442); catalogued as rs1214557542, COSV65367099; called by muse, mutect2
- PCDHA9 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.143); catalogued as rs868949639; called by muse, mutect2
- PCDHAC1 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.651); catalogued as rs868907682, COSV53865388; called by muse, mutect2
- PCDHB15 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 84/1131 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV50859515; called by muse, mutect2
- PDE12 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs978437808, COSV60819195; called by muse, mutect2
- PEX14 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 87/507 reads (17%) | catalogued as COSV63062603; called by muse, mutect2, varscan2
- PGBD5 | c.1099C>T p.P367S (on ENST00000525115; = p.P436S on NM_001258311.2) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV100358913; called by muse, mutect2
- PKD1 | c.6670C>A p.P2224T | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV51920328; called by muse, mutect2
- PKD2L1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100559351; called by muse, mutect2
- PKHD1 | c.7549C>T p.P2517S | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs138859228; called by muse, mutect2
- PKHD1 | c.6209G>A p.W2070* | Nonsense Mutation (SNP) | VAF 26/449 reads (6%) | catalogued as CM041059; called by muse, mutect2
- PKLR | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV100713104; called by muse, mutect2, varscan2
- PKM | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV58786908; called by muse, mutect2
- PLCB3 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54191661; called by muse, mutect2
- PLEC | c.11378G>A p.R3793Q (on ENST00000322810 / NM_201380.4; = p.R3683Q on NM_000445.5) | Missense Mutation (SNP) | VAF 44/669 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs370136466; called by muse, mutect2
- PLEKHA7 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs994546822, COSV60580215; called by muse, mutect2
- PLPPR4 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 31/283 reads (11%) | catalogued as COSV64564469; called by muse, mutect2, varscan2
- PLXNB2 | c.4028C>G p.S1343W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834074; called by mutect2, varscan2
- POM121L12 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 27/453 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1333529315, COSV101374835; called by muse, mutect2
- PON3 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 20/376 reads (5%) | catalogued as COSV55702746; called by muse, mutect2
- POU4F3 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57943280; called by muse, mutect2
- PPHLN1 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as COSV56735286; called by muse, mutect2, varscan2
- PPIP5K2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782219353; called by muse, mutect2
- PPP1R3A | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52893934; called by muse, mutect2
- PPP1R3F | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs781965989; called by muse, mutect2
- PRKG2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV52330133, COSV52333448; called by muse, mutect2
- PRM1 | c.112+1G>A p.X38_splice | Splice Site (SNP) | VAF 36/522 reads (7%) | catalogued as rs1433033495; called by muse, mutect2
- PRR14L | c.3117T>G p.F1039L | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57887387; called by muse, mutect2
- PRSS1 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 36/512 reads (7%) | catalogued as rs1200820723, COSV104411415; called by muse, mutect2
- PRSS35 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63800138; called by muse, mutect2
- PRSS58 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.96); catalogued as rs200182282; called by muse, mutect2
- PTF1A | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV64735060; called by muse, mutect2
- PTPRF | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1232705923, COSV100740530; called by muse, mutect2, varscan2
- PTPRQ | c.2416G>A p.E806K (on ENST00000616559; = p.E764K on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV57033462; called by muse, mutect2
- QPCT | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58120674; called by muse, mutect2
- RAB11FIP2 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1031835668; called by muse, mutect2
- RAB42 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1345998588; called by muse, mutect2, varscan2
- RAET1L | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 20/356 reads (6%) | catalogued as rs1444288323; called by muse, mutect2
- RALYL | c.598A>T p.K200* | Nonsense Mutation (SNP) | VAF 12/181 reads (7%) | catalogued as COSV72823936; called by muse, mutect2
- RASSF7 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.57); catalogued as rs1032428206; called by muse, mutect2
- RBM4 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 49/703 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV59519544; called by muse, mutect2
- RGS4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1482287208, COSV63357011, COSV63358209; called by muse, mutect2
- RGS9 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs755297304, COSV52224127; called by muse, mutect2, varscan2
- RLF | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1468285245; called by muse, mutect2
- RP1 | c.3937A>G p.K1313E | Missense Mutation (SNP) | VAF 54/662 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55127227; called by muse, mutect2
- RPTN | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1261334351; called by muse, mutect2, varscan2
- RTL3 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV58183278; called by muse, mutect2
- RTN1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV50718907; called by muse, mutect2
- RYR3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211980; called by muse, mutect2
- S100A7L2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs943172702, COSV100906869, COSV64194894; called by muse, mutect2
- S100A7L2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1209137965, COSV64194949, COSV64195328; called by muse, mutect2
- SAMD7 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV59417629; called by muse, mutect2
- SAMHD1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 32/428 reads (7%) | catalogued as COSV53432123; called by muse, mutect2
- SCG2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1420323179; called by muse, mutect2
- SCNN1A | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985419660; called by muse, mutect2
- SDK2 | c.2150G>A p.S717N | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1199758118; called by muse, mutect2
- SDR42E2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.802); catalogued as rs1027761752; called by muse, mutect2
- SEMG2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); catalogued as COSV65647820; called by muse, mutect2
- SERPINA10 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762102205; called by muse, mutect2
- SERPINA10 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1275866291; called by muse, mutect2
- SERPINA10 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1227298146, COSV56227398; called by muse, mutect2, varscan2
- SERPINA4 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV54069016; called by muse, mutect2
- SERPINB11 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1376427177; called by muse, mutect2
- SERPINB3 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | catalogued as rs904378635; called by muse, mutect2
- SERPINB4 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as COSV100345600; called by muse, mutect2
- SEZ6L | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50699220; called by muse, varscan2
- SH3TC2 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 44/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60460837; called by muse, mutect2, varscan2
- SHANK2 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs371473462; called by muse, mutect2, varscan2
- SHC4 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1489451383; called by muse, mutect2
- SHKBP1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV99184077; called by muse, mutect2
- SI | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs886058144; ClinVar: uncertain significance; called by muse, mutect2
- SI | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1177242379; called by muse, mutect2
- SI | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 16/291 reads (5%) | catalogued as COSV100017282, COSV52265183; called by muse, mutect2
- SIRPD | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV67546543; called by muse, mutect2
- SLC16A10 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100920828; called by muse, mutect2
- SLC35C1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58480877; called by muse, mutect2
- SLC9B1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1398963576; called by muse, mutect2
- SLC9C2 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV62946930; called by muse, mutect2
- SLCO5A1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV52656781; called by muse, mutect2
- SLITRK2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as COSV59423570; called by muse, mutect2, varscan2
- SLITRK2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99045887; called by muse, mutect2, varscan2
- SLITRK4 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62023896; called by muse, mutect2, varscan2
- SLX4 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 34/515 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1234065208; called by muse, mutect2
- SMPDL3B | c.691-1G>A p.X231_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as rs201032697; called by mutect2, varscan2
- SNPH | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs780301142; called by mutect2, varscan2
- SOAT2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037462; called by muse, mutect2
- SORL1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764615209; called by muse, mutect2, varscan2
- SP140L | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.201); catalogued as rs1345507626; called by muse, mutect2, varscan2
- SP7 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.175); catalogued as rs961195607; called by muse, mutect2, varscan2
- SPATA18 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54645025; called by muse, mutect2
- SPATS2L | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 32/449 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV62350556; called by muse, mutect2
- SPC24 | c.487+6C>T | Splice Region (SNP) | VAF 18/161 reads (11%) | catalogued as rs1157344768; called by muse, mutect2, varscan2
- SPC24 | c.487+5C>T | Splice Region (SNP) | VAF 16/152 reads (11%) | catalogued as rs754699451, COSV104436938; called by mutect2, varscan2
- SPHKAP | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs148914025, COSV60868610; called by mutect2, varscan2
- SRD5A2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM081828; called by muse, mutect2
- SRRM4 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 39/540 reads (7%) | catalogued as rs1428404875, COSV99938599; called by muse, mutect2
- SST | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99809797; called by muse, mutect2
- ST3GAL1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 19/322 reads (6%) | PolyPhen benign (0.011); catalogued as rs1348384890; called by muse, mutect2
- ST8SIA5 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 70/692 reads (10%) | PolyPhen possibly damaging (0.453); catalogued as rs776470494; called by muse, mutect2
- STX11 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62449348; called by muse, mutect2
- STXBP4 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277307224; called by muse, mutect2
- STXBP5L | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1347085003, COSV56514279, COSV56521455; called by muse, mutect2
- STYXL1 | c.73T>A p.L25I | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV50390133; called by muse, mutect2
- TAF5L | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1233470493, COSV51077561; called by muse, mutect2
- TCHH | c.4163G>A p.R1388Q | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1197997251, COSV64276873; called by muse, mutect2, varscan2
- TCN1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV57252163; called by muse, mutect2
- TENM3 | c.7508C>T p.A2503V | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV69309073; called by muse, mutect2, varscan2
- TERT | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57236930; called by muse, mutect2
- TEX11 | c.565G>A p.E189K (on ENST00000344304; = p.E174K on NM_031276.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104418235; called by muse, mutect2, varscan2
- TEX13A | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs782232598, COSV61171493; called by muse, mutect2, varscan2
- TEX13C | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as rs1250984676; called by muse, mutect2, varscan2
- TFAP2D | c.826T>A p.L276I | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99147357, COSV99148083; called by muse, mutect2
- TFAP2E | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as rs1038809834; called by muse, mutect2, varscan2
- TIAM1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753525414, COSV54552084; called by mutect2, varscan2
- TMEM125 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs759856226; called by muse, mutect2, varscan2
- TMEM132B | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867174287, COSV54759616; called by muse, mutect2
- TMEM132D | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV70605139, COSV70615563; called by muse, mutect2
- TMEM214 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs773408223; called by muse, mutect2, varscan2
- TMPRSS4 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs766360701, COSV71108753; called by mutect2, varscan2
- TNC | c.4933G>A p.G1645R | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV60790954; called by muse, mutect2
- TNRC18 | c.4577C>T p.P1526L | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101269692; called by muse, mutect2
- TNXB | c.5830C>T p.P1944S (on ENST00000647633; = p.P1697S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV64474032; called by muse, mutect2, varscan2
- TOR1AIP2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.012); catalogued as rs1461065734, COSV100857560; called by muse, mutect2
- TRIOBP | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 48/634 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs763229296, COSV60376266, COSV60380444; called by muse, mutect2
- TRPM6 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV62518209; called by muse, mutect2
- TRPM8 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100223858; called by muse, mutect2
- TRPV6 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63893201; called by muse, mutect2
- TUBA4A | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs769120095, COSV99944635; called by mutect2, varscan2
- UBASH3B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs142722431; called by mutect2, varscan2
- UBR4 | c.9119C>T p.S3040F | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV64387825; called by muse, mutect2
- USH2A | c.13940G>A p.G4647E | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.162); catalogued as rs1210072997, COSV56401141; called by muse, mutect2, varscan2
- USH2A | c.9455C>T p.P3152L | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56399787; called by muse, mutect2
- USP17L7 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 30/291 reads (10%) | catalogued as rs1285602004; called by muse, mutect2, varscan2
- USP42 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as rs1385410002, COSV100084552; called by muse, mutect2
- VCAN | c.5713G>A p.E1905K | Missense Mutation (SNP) | VAF 40/608 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV54104376; called by muse, mutect2
- VSTM2B | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59259152; called by muse, mutect2
- WDR87 | c.3586G>A p.G1196R | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1286401192; called by muse, mutect2
- WDR87 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1371041062, COSV58192838; called by muse, mutect2, varscan2
- WWC1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 23/431 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54659001; called by muse, mutect2
- XAGE2 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1349548753, COSV53684666; called by muse, mutect2, varscan2
- ZC3H12B | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.992); catalogued as rs1180867720, COSV59047420; called by muse, mutect2, varscan2
- ZDBF2 | c.6823C>T p.P2275S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as rs1427199780; called by muse, mutect2, varscan2
- ZFHX4 | c.7840C>T p.P2614S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1043045004, COSV99267064; called by muse, mutect2, varscan2
- ZFP64 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | catalogued as COSV99402059; called by muse, mutect2, varscan2
- ZNF16 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1479852089, COSV52764654; called by muse, mutect2
- ZNF189 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1046239728; called by muse, mutect2
- ZNF281 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 52/730 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1332663345; called by muse, mutect2
- ZNF30 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV57853740; called by muse, mutect2
- ZNF511 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 62/862 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62919755; called by muse, mutect2
- ZNF641 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1383594530; called by muse, mutect2
- ZNF716 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV101348474; called by muse, mutect2
- ZYG11A | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs537263056; called by muse, mutect2, varscan2
- ABCA13 | c.12763C>T p.P4255S | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.988); called by muse, mutect2
- ABCA13 | c.12884G>T p.C4295F | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB8 | c.1238C>T p.S413F (on ENST00000297504 / NM_001282291.2; = p.S396F on NM_007188.5) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCG4 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABL1 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC138647.1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- AC242842.3 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 22/790 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); called by muse, mutect2
- ACACA | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- ACACA | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2
- ACADVL | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- ACRV1 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- ACVR1C | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADAM21 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.104); called by muse, mutect2
- ADAMTS19 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- ADAMTS19 | c.3335G>A p.G1112E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ADARB2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- ADCY10 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ADGRB3 | c.3182G>A p.R1061K | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2
- ADORA2B | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADRA1D | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- AGBL2 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AGFG2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGTR2 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- AGXT | c.846+8G>A | Splice Region (SNP) | VAF 44/372 reads (12%) | called by muse, varscan2
- AHNAK | c.16690C>T p.P5564S | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- AHRR | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 50/638 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2
- AIF1L | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AIP | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 32/449 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- AJM1 | c.2701C>T p.H901Y | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AK9 | c.2591G>A p.R864K | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AKAP1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2
- AKAP13 | c.5393C>T p.P1798L (on ENST00000394518 / NM_007200.5; = p.P1802L on NM_006738.6) | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2
- AKR7A3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 96/587 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AL645922.1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 43/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALAS2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALDH2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH3A1 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 46/627 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.287); called by muse, mutect2
- AMOTL2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.079); called by muse, mutect2
- ANK3 | c.7784T>G p.F2595C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANK3 | c.7102G>A p.G2368R | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ANK3 | c.3706G>A p.G1236R (on ENST00000280772 / NM_001320874.2; = p.G370R on NM_001149.3) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ANKS1A | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); called by muse, mutect2
- ANO1 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); called by muse, mutect2
- AP3B2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- AP4B1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 26/489 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOB | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); called by muse, mutect2
- APOBEC3B | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 36/684 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- ARHGEF1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ARPP21 | c.1342T>A p.Y448N | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- ARSL | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ASPA | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.331); called by muse, mutect2
- B4GALNT4 | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- B4GALT5 | c.255T>A p.Y85* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- B4GALT6 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL2L12 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); called by muse, mutect2
- BCL6B | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BCO1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.21); called by muse, mutect2
- BCO1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2
- BET1 | c.51C>G p.N17K | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- BFAR | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- BMP5 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.239); called by muse, mutect2
- BNIP5 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- BRDT | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2
- BTBD8 | c.4765C>T p.H1589Y (on ENST00000636805 / NM_001376131.1; = p.H1076Y on NM_015237.4) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2
- C4orf54 | c.5120C>T p.S1707F | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- C5orf15 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- C6orf118 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.605); called by muse, mutect2
- CABIN1 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CACNA1D | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- CACNA1D | c.4177C>T p.P1393S (on ENST00000350061 / NM_001128840.3; = p.P1413S on NM_000720.4) | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- CAD | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CALB2 | c.220A>C p.K74Q | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2
- CAMTA1 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPRIN1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 48/679 reads (7%) | called by muse, mutect2
- CASR | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.063); called by muse, mutect2
- CCBE1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.18523C>T p.Q6175* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- CCDC168 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CCDC178 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- CCHCR1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.429); called by muse, mutect2
- CCIN | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2
- CCL1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.051); called by muse, mutect2
- CD200R1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); called by muse, mutect2
- CDCA4 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CDH17 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CFAP43 | c.4292G>A p.R1431K | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CFAP47 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CFAP54 | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- CFAP54 | c.5177T>G p.L1726R | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CFAP61 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2
- CGN | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 61/446 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CHAF1A | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHKB | c.1116C>T p.D372= | Splice Region (SNP) | VAF 42/576 reads (7%) | called by muse, mutect2
- CHST2 | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CLCA4 | c.2321G>A p.W774* | Nonsense Mutation (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- CLEC3B | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); called by muse, mutect2
- CLIC6 | c.1438G>A p.D480N (on ENST00000360731 / NM_001317009.2; = p.D462N on NM_053277.3) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2
- CMSS1 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNGA2 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNKSR3 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CNTN3 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- COL11A1 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2
- COL11A2 | c.1362C>T p.F454= (on ENST00000341947 / NM_080680.3; = p.F347= on NM_080679.2) | Splice Region (SNP) | VAF 43/646 reads (7%) | called by muse, mutect2
- COL14A1 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL14A1 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- COL19A1 | c.340A>T p.K114* | Nonsense Mutation (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- COL20A1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL25A1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL27A1 | c.4378G>A p.G1460R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL4A2 | c.4139-8C>T | Splice Region (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- COL4A3 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A3 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A3 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2
- COL6A3 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); called by muse, mutect2
- COL9A2 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.299); called by muse, varscan2
- COLEC12 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CPA4 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8369C>T p.S2790L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CSF3R | c.996G>A p.R332= | Splice Region (SNP) | VAF 56/416 reads (13%) | called by muse, varscan2
- CSMD2 | c.1080-1G>A p.X360_splice | Splice Site (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- CTHRC1 | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.164); called by muse, mutect2
- CTSA | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 21/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- CTTNBP2 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- CUL4B | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, varscan2
- CUZD1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CYP21A2 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 48/423 reads (11%) | called by muse, mutect2, varscan2
- CYP4A11 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- DBF4B | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- DDIT4 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- DESI1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DGCR8 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); called by muse, mutect2
- DHCR24 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DISP1 | c.3629A>G p.Y1210C | Missense Mutation (SNP) | VAF 44/658 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2
- DNAH11 | c.5333C>T p.S1778F | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- DNAH2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2
- DNAH2 | c.8663T>C p.I2888T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- DNAH5 | c.11380G>A p.E3794K | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAH6 | c.3587C>T p.S1196L | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH7 | c.11536C>T p.P3846S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- DNAH9 | c.4884C>A p.H1628Q | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- DOK7 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- DSC2 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DSC2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DTNA | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DYRK4 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2
- DZANK1 | c.733C>T p.P245S (on ENST00000262547 / NM_001099407.1; = p.P46S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- EBAG9 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); called by muse, mutect2
- EFCAB3 | c.848A>T p.K283I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- EFHC2 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); called by muse, mutect2
- EGR1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2
- EGR2 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 41/496 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- EHHADH | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.424); called by muse, mutect2
- EIF2B3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.045); called by muse, mutect2
- EIF2S3B | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF4EBP1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- EML5 | c.5613G>A p.W1871* (on ENST00000380664; = p.W1879* on NM_183387.3) | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2
- ENPP2 | c.1661C>T p.P554L (on ENST00000075322 / NM_001040092.3; = p.P606L on NM_006209.5) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.206); called by muse, mutect2
- ENPP2 | c.1660C>T p.P554S (on ENST00000075322 / NM_001040092.3; = p.P606S on NM_006209.5) | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.21); called by muse, mutect2
- ENTPD8 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPAS1 | c.1831G>C p.A611P | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- EPB41L1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 44/495 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EQTN | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ERBB4 | c.1163A>T p.K388I | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ERC2 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ERICH3 | c.2951G>A p.R984K | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ERICH6B | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.111); called by muse, mutect2
- ERVFRD-1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.651); called by muse, mutect2
- EXD2 | c.1220C>T p.S407F (on ENST00000312994 / NM_001193362.1; = p.S282F on NM_018199.3) | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- EXPH5 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- FAM13A | c.3067A>G p.M1023V | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- FAM13C | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- FAM47E | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- FAM71B | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- FARSA | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAS | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 34/519 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAT1 | c.2357A>T p.D786V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FAT2 | c.11177C>T p.P3726L | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- FBF1 | c.1210C>T p.P404S (on ENST00000586717; = p.P418S on NM_001319193.1) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2
- FBLN2 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2
- FBN1 | c.1274T>G p.I425S | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- FBN2 | c.5305G>A p.G1769S | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO44 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- FBXW7 | c.820C>T p.P274S (on ENST00000281708 / NM_001349798.2; = p.P194S on NM_018315.5) | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCGBP | c.10445G>A p.G3482D | Missense Mutation (SNP) | VAF 27/426 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2
- FCGBP | c.10315C>T p.Q3439* | Nonsense Mutation (SNP) | VAF 44/666 reads (7%) | called by muse, mutect2
- FCGR3B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FIBIN | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FLG | c.9749G>A p.G3250D | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLG | c.9443G>T p.R3148M | Missense Mutation (SNP) | VAF 47/617 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, varscan2
- FLG | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 87/801 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FLII | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMN1 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- FMR1 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 22/197 reads (11%) | called by muse, mutect2, varscan2
- FOXD4L1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 73/1277 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); called by muse, mutect2
- FOXR1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2
- FRAS1 | c.8927C>T p.S2976F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FREM2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FREM2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FREM2 | c.6541C>T p.P2181S | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2
- FREM2 | c.6542C>T p.P2181L | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2
- FSIP2 | c.11851G>A p.E3951K | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- FSTL5 | c.1814C>A p.T605N | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- FZD3 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- GALNT3 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAPVD1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- GAREM1 | c.2405G>A p.W802* (on ENST00000269209 / NM_001242409.2; = p.W801* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- GAREM1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GCSAML | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); called by muse, mutect2
- GFI1B | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 34/547 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- GGCX | c.374-4C>T | Splice Region (SNP) | VAF 22/450 reads (5%) | called by muse, mutect2
- GGCX | c.374-5C>T | Splice Region (SNP) | VAF 22/450 reads (5%) | called by muse, mutect2
- GJA10 | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GLMN | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLRA2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- GLUD2 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GMNC | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- GNAS | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2
- GNAT2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 45/679 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.632); called by muse, mutect2
- GNRHR | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPATCH8 | c.3059C>T p.S1020F | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2
- GPC4 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by mutect2, varscan2
- GPNMB | c.1523C>T p.A508V (on ENST00000381990 / NM_001005340.2; = p.A496V on NM_002510.3) | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- GPRIN1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2
- GRIK2 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2
- GRIN2A | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- GRIN2C | c.2645C>A p.P882Q | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GTF2H1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.759); called by muse, mutect2
- GTSE1 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- GUCY2D | c.2770-1G>A p.X924_splice | Splice Site (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2, varscan2
1,250 further variants in this file (391 protein-altering or splice-affecting, 592 silent, 267 other) are not listed here.
